Gene-level copy-number profile of specimen HCM-STAN-0909-C16-85A from HCMI case HCM-STAN-0909-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen HCM-STAN-0909-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fa232262-4bb8-40f2-8b0a-acaef3ea7585.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0909-C16-11A (ffpe scrolls); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/c39d0927-6da9-44c6-ab62-a2157af6fbe0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,394; copy number 2: 52,765; copy number 3: 3,182; copy number 4: 36; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,789,376, 1 gene: NCF1.
- chr17:19,061,912–19,062,669, 1 gene: SNORD3B-1.
- chr17:46,274,784–46,361,797, 3 genes: ARL17B, LRRC37A, RN7SL656P.
- chr21:43,053,191–43,076,943, 1 gene: CBS.
- chr22:21,354,563–21,358,067, 1 gene: LINC01651.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,155,406–42,181,338, 3 genes, copy number 5: AL096814.1, AL096814.2, GUCA1A.

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
